Somatic mutation profile of tumor specimen TCGA-DX-A2J0-01A (aliquot TCGA-DX-A2J0-01A-11D-A21Q-09) from TCGA case TCGA-DX-A2J0, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 61.2 years (22,369 days).
Specimen TCGA-DX-A2J0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e7e5c02-5a8d-4a83-9058-8bdad5fae998.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A2J0-10A (Blood Derived Normal), aliquot TCGA-DX-A2J0-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a64266f-b72d-4996-8efb-4d85f494e6d1

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs760428119, CM053750, COSV59872912; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMY2B | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs144281226; called by muse, mutect2, varscan2
- CEP350 | c.2378del p.T793Ifs*8 | Frame Shift Del (DEL) | VAF 12/19 reads (63%) | catalogued as COSV62609417; called by mutect2, varscan2
- FAM151A | c.834C>G p.D278E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs759552783; called by muse, mutect2, varscan2
- GRID1 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs777631027; called by muse, varscan2
- RNF113A | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV65097124; called by muse, mutect2, varscan2
- TMEM59L | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1215982075; called by muse, mutect2, varscan2
- ZNF761 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs748200943, COSV61889548; called by muse, mutect2, varscan2
- ADAM33 | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ALG2 | c.810T>A p.Y270* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2
- CPT1A | c.1925A>T p.H642L | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDR2 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUT1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.69); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- GPRIN3 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- IL12RB2 | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- KRT1 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUZP2 | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MBL2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NLRP14 | c.3257A>G p.D1086G | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NSUN6 | c.810C>G p.N270K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLAMF6 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SMG6 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2
- SRGAP2 | c.1465A>C p.R489= (on ENST00000624873 / NM_001170637.4; = p.R490= on NM_015326.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 23/31 reads (74%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TEX15 | c.7862del p.N2621Ifs*5 (on ENST00000256246; = p.N3004Ifs*5 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- TRAV8-1 | c.129C>A p.N43K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRIOBP | c.4723G>A p.A1575T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUBGCP6 | c.4397C>G p.A1466G | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- XPOT | c.1878G>T p.E626D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.2565C>T p.R855= (on ENST00000520002; = p.R854= on NM_033225.6) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs372780899; called by muse, mutect2, varscan2
- ITGA7 | c.3303G>A p.L1101= (on ENST00000555728; = p.L1057= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- PTPRR | c.531T>C p.S177= | Silent (SNP) | VAF 28/380 reads (7%) | called by muse, mutect2
- TCF4 | c.201G>A p.P67= | Silent (SNP) | VAF 45/63 reads (71%) | catalogued as rs775657966; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP2 | c.9855T>C p.D3285= (on ENST00000628543; = p.D3460= on NM_152381.6) | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- IGHG1 | chr14:105740156 G>A | 3'Flank (SNP) | VAF 31/165 reads (19%) | catalogued as rs779219185; called by muse, mutect2, varscan2
